Somatic mutation profile of tumor specimen 0DP4Q7 from CCDI case PBCCYT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.3 years (461 days).
Specimen 0DP4Q7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fdb7e7ad-4a59-4214-8433-d2e3b1605c35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DP4P2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e825e52d-193e-4fa1-b182-82c6a51b9847

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NUP153 | c.2601C>G p.D867E | Missense Mutation (SNP) | VAF 127/1160 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs201282375; called by muse, mutect2, varscan2
- OPLAH | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 69/681 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs782187975; called by muse, mutect2, varscan2
- AFAP1L1 | c.336C>T p.D112= | Silent (SNP) | VAF 60/468 reads (13%) | called by muse, mutect2
- TBC1D9 | c.1359C>T p.G453= | Silent (SNP) | VAF 114/1213 reads (9%) | catalogued as rs755013894; called by muse, mutect2
